Somatic mutation profile of cancer-model specimen HCM-BROD-0254-C49-85M (Adherent Cell Line, passage 11; aliquot HCM-BROD-0254-C49-85M-01D-A79L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0254-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 11.9 years (4,358 days).
Specimen HCM-BROD-0254-C49-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59b83b0e-653f-4ccf-ac76-4510285000ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0254-C49-10A (Blood Derived Normal), aliquot HCM-BROD-0254-C49-10A-01D-A79L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/837d4f5b-e126-4065-999a-a28e8e8ec8a6

The open-access MAF lists 89 somatic variants for this specimen: 66 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 21, Nonsense Mutation 4, Frame Shift Ins 3, Intron 2, Splice Region 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPT2 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as rs74315293, CM920217, COSV53760198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSL6 | c.1282G>A p.V428M (on ENST00000379240; = p.V453M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/351 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV57296082; called by muse, mutect2
- ANKRD18B | c.1164G>T p.M388I | Missense Mutation (SNP) | VAF 25/475 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs1338234688; called by muse, mutect2
- CCDC168 | c.14248G>A p.E4750K | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.299); catalogued as COSV104400384; called by muse, mutect2, varscan2
- CDC42SE1 | c.213G>T p.R71S | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.765); catalogued as COSV61785509; called by muse, mutect2
- CLCN1 | c.1895C>A p.T632N | Missense Mutation (SNP) | VAF 42/321 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV100578275; called by muse, mutect2, varscan2
- CYP11B1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs544670837, COSV52824806, COSV52825753; called by muse, mutect2, varscan2
- DGKD | c.2479G>A p.G827R (on ENST00000264057 / NM_152879.3; = p.G783R on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/351 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374982750, COSV51095884; called by muse, mutect2, varscan2
- GFPT2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 57/548 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs537515231; called by muse, mutect2, varscan2
- GPR17 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 57/620 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1372356338; called by muse, mutect2
- INHBE | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 27/331 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56988419, COSV99875240; called by muse, mutect2
- NOTCH4 | c.4907C>T p.T1636I | Missense Mutation (SNP) | VAF 141/614 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66682790; called by muse, mutect2, varscan2
- PIK3R2 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 104/456 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs773024898, COSV53226279; called by muse, mutect2, varscan2
- RHEX | c.255G>T p.R85S | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.367); catalogued as COSV58982138; called by muse, mutect2, varscan2
- RTF1 | c.777G>A p.Q259= | Splice Region (SNP) | VAF 14/164 reads (9%) | catalogued as COSV67479084; called by muse, mutect2
- SALL3 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 63/468 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as rs1197931609; called by muse, mutect2, varscan2
- TMEM63B | c.1738G>A p.G580S | Missense Mutation (SNP) | VAF 139/415 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52482334; called by muse, mutect2, varscan2
- ABCA10 | c.3752T>C p.M1251T | Missense Mutation (SNP) | VAF 60/442 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- ADH4 | c.1038C>A p.F346L | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ARHGAP36 | c.116C>A p.P39Q | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2
- ARHGDIA | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 70/537 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF12 | c.2190-1G>A p.X730_splice | Splice Site (SNP) | VAF 35/304 reads (12%) | called by muse, mutect2, varscan2
- BID | c.421G>C p.D141H (on ENST00000317361 / NM_197966.2; = p.D95H on NM_001196.4) | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf127 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- CAMK2G | c.1276C>T p.R426* (on ENST00000423381 / NM_001367518.1; = p.R363* on NM_001222.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 80/395 reads (20%) | called by muse, mutect2, varscan2
- CD6 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 44/566 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- CWF19L2 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DCAF4L1 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNMT3B | c.256G>C p.V86L | Missense Mutation (SNP) | VAF 61/632 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2
- DOCK4 | c.1855A>G p.T619A | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.441); called by muse, mutect2
- FAM13B | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- FGD3 | c.2162G>A p.G721D | Missense Mutation (SNP) | VAF 35/435 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2
- ITPR3 | c.5362_5364delinsTT p.V1788Ffs*6 | Frame Shift Del (DEL) | VAF 65/370 reads (18%) | called by pindel, varscan2*
- KANK3 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 125/492 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- KANSL1 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 82/544 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by mutect2, varscan2
- KCTD3 | c.1982G>A p.R661K | Missense Mutation (SNP) | VAF 15/301 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.444); called by muse, mutect2
- LAMB4 | c.2770G>A p.A924T | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- LYST | c.5654G>C p.C1885S | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- MAPRE3 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 50/359 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MYO7A | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 89/666 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- MYRF | c.2906A>C p.Q969P (on ENST00000278836 / NM_001127392.3; = p.Q934P on NM_013279.4) | Missense Mutation (SNP) | VAF 34/938 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- NMT1 | c.1473T>A p.V491= | Splice Region (SNP) | VAF 31/586 reads (5%) | called by muse, mutect2
- NOTCH1 | c.3575G>A p.C1192Y | Missense Mutation (SNP) | VAF 63/959 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ODF2 | c.1366G>T p.G456* (on ENST00000434106 / NM_153433.2; = p.G432* on NM_002540.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 45/275 reads (16%) | called by muse, mutect2, varscan2
- ODF2 | c.1367G>C p.G456A (on ENST00000434106 / NM_153433.2; = p.G432A on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- OR1R1P | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.052); called by muse, mutect2
- OR2L3 | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.005); called by muse, mutect2
- OR4A8 | c.200T>C p.I67T | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PER3 | c.952C>G p.L318V | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLEKHG4 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 68/353 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PTK6 | c.681_682dup p.H228Rfs*13 | Frame Shift Ins (INS) | VAF 86/481 reads (18%) | called by mutect2, pindel, varscan2
- RBM14 | c.1254_1255insCA p.A419Qfs*54 | Frame Shift Ins (INS) | VAF 69/603 reads (11%) | called by mutect2, pindel, varscan2
- RCAN2 | c.440A>G p.K147R | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RMND5A | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- RTL1 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.205); called by muse, mutect2
- SCARF2 | c.2054C>T p.A685V | Missense Mutation (SNP) | VAF 98/474 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.176); called by muse, varscan2
- SERPINB4 | c.1102C>A p.P368T | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC10A7 | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 31/261 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SLC45A2 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 515/515 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLCO2B1 | c.150dup p.F51Vfs*100 | Frame Shift Ins (INS) | VAF 40/363 reads (11%) | called by mutect2, pindel, varscan2
- TLN1 | c.6754G>T p.D2252Y | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TMCC2 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 34/346 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TNRC6C | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TRIM49 | c.1210A>T p.K404* | Nonsense Mutation (SNP) | VAF 40/390 reads (10%) | called by muse, mutect2, varscan2
- TRIP10 | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 25/304 reads (8%) | called by muse, mutect2
- UMPS | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ALDH1A1 | c.564C>T p.N188= | Silent (SNP) | VAF 55/276 reads (20%) | called by muse, mutect2, varscan2
- B3GNT7 | c.999C>T p.C333= | Silent (SNP) | VAF 83/750 reads (11%) | called by muse, mutect2, varscan2
- BCOR | c.3867C>T p.G1289= (on ENST00000378444 / NM_001123385.2; = p.G1255= on NM_017745.6) | Silent (SNP) | VAF 48/180 reads (27%) | called by muse, mutect2, varscan2
- BID | c.420G>A p.G140= (on ENST00000317361 / NM_197966.2; = p.G94= on NM_001196.4) | Silent (SNP) | VAF 39/326 reads (12%) | called by muse, mutect2, varscan2
- BIRC6 | c.8304C>A p.G2768= | Silent (SNP) | VAF 62/300 reads (21%) | catalogued as rs766845760; called by muse, mutect2, varscan2
- CATSPERG | c.2601G>A p.G867= | Silent (SNP) | VAF 74/252 reads (29%) | catalogued as COSV53051110; called by muse, mutect2, varscan2
- CBX6 | c.1053C>T p.S351= | Silent (SNP) | VAF 256/387 reads (66%) | catalogued as rs775494009, COSV99328049; called by muse, mutect2, varscan2
- DHX40 | c.81G>A p.E27= | Silent (SNP) | VAF 31/619 reads (5%) | called by muse, mutect2
- MGAM | c.5490G>A p.T1830= | Silent (SNP) | VAF 54/300 reads (18%) | catalogued as rs752684574, COSV72073855; called by muse, mutect2, varscan2
- OR2L2 | c.888G>T p.V296= | Silent (SNP) | VAF 30/243 reads (12%) | called by muse, mutect2, varscan2
- OR5AR1 | c.222C>G p.S74= | Silent (SNP) | VAF 22/595 reads (4%) | catalogued as COSV57255293; called by muse, mutect2
- PIK3AP1 | c.219G>A p.A73= | Silent (SNP) | VAF 89/508 reads (18%) | catalogued as rs773426752; called by muse, mutect2, varscan2
- POPDC3 | c.630G>T p.V210= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- PRLR | c.249C>A p.P83= | Silent (SNP) | VAF 24/386 reads (6%) | called by muse, mutect2
- SCT | c.6C>A p.A2= | Silent (SNP) | VAF 83/387 reads (21%) | called by muse, mutect2, varscan2
- SLC15A4 | c.378C>T p.P126= | Silent (SNP) | VAF 111/549 reads (20%) | catalogued as rs1242161004; called by muse, mutect2, varscan2
- SMPD1 | c.457C>T p.L153= | Silent (SNP) | VAF 23/598 reads (4%) | catalogued as COSV54966338; called by muse, mutect2
- STAB1 | c.1182G>C p.A394= | Silent (SNP) | VAF 87/411 reads (21%) | called by muse, mutect2, varscan2
- THSD7A | c.507G>A p.A169= | Silent (SNP) | VAF 102/337 reads (30%) | catalogued as rs867019373, COSV101448676; called by muse, mutect2, varscan2
- TRNT1 | c.1215G>A p.G405= | Silent (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- ZNF653 | c.690G>A p.P230= | Silent (SNP) | VAF 38/572 reads (7%) | catalogued as rs150907206; called by muse, mutect2
- KCNQ1 | c.1514+26091C>G | Intron (SNP) | VAF 74/549 reads (13%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5462C>T | Intron (SNP) | VAF 101/783 reads (13%) | catalogued as rs1056453515; called by muse, mutect2, varscan2
